Somatic mutation profile of tumor specimen 0DF86L from CCDI case PBBRVM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.3 years (1,553 days).
Specimen 0DF86L: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5bffb1da-8b51-4afb-97fb-29b0cf5b56af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DF86M (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8430979-bc58-407f-8aa2-c5eb76638536

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADRA1B | c.1105G>T p.G369C | Missense Mutation (SNP) | VAF 162/290 reads (56%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.038); catalogued as COSV60701874; called by muse, mutect2, varscan2
- CTNNBL1 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 266/651 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as rs753242321, COSV63743751, COSV63745890; called by muse, mutect2, varscan2
- DEDD2 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 209/497 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs763772677; called by muse, mutect2, varscan2
- NRXN1 | c.3683T>C p.V1228A | Missense Mutation (SNP) | VAF 261/555 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60525552; called by muse, mutect2, varscan2
- BBX | c.2071G>T p.E691* | Nonsense Mutation (SNP) | VAF 198/425 reads (47%) | called by muse, mutect2, varscan2
- SPRED2 | c.1064C>T p.S355L | Missense Mutation (SNP) | VAF 33/594 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
